Somatic mutation profile of tumor specimen TCGA-CC-A8HV-01A (aliquot TCGA-CC-A8HV-01A-11D-A35Z-10) from TCGA case TCGA-CC-A8HV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 51.8 years (18,935 days).
Specimen TCGA-CC-A8HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5ebb318-1888-4faa-ab5f-11dc173b7262.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A8HV-10A (Blood Derived Normal), aliquot TCGA-CC-A8HV-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f41e8d64-f332-4cf1-bc71-c091d2ae1896

The open-access MAF lists 157 somatic variants for this specimen: 116 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 35, Nonsense Mutation 7, Frame Shift Del 4, RNA 3, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 46/63 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AAR2 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs147662826, COSV100299425; called by muse, mutect2, varscan2
- ACCS | c.128A>T p.K43M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV99772965; called by muse, mutect2, varscan2
- ADAMTS14 | c.41T>G p.L14W | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1372074475, COSV100941828; called by muse, mutect2
- ADM5 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV99773639; called by muse, mutect2, varscan2
- ADPRHL1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as rs375108772; called by muse, mutect2, varscan2
- ANO1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | catalogued as COSV100304433; called by muse, mutect2, varscan2
- APBA2 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs765311604, COSV68796772; called by muse, mutect2, varscan2
- ARF1 | c.405T>G p.N135K | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV99683335; called by muse, mutect2, varscan2
- ATP1A4 | c.1427C>A p.A476E | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs757229274, COSV100927637, COSV63628029; called by muse, mutect2, varscan2
- ATP2A2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100428877; called by muse, mutect2, varscan2
- BCLAF1 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.882); catalogued as rs1350215614, COSV62140786; called by muse, mutect2, varscan2
- CACNA2D3 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as rs376433361, COSV99876777; called by muse, mutect2, varscan2
- CBFB | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.596); catalogued as COSV99325957; called by muse, mutect2, varscan2
- CDH22 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV100952977; called by muse, mutect2, varscan2
- CEP44 | c.494T>G p.M165R | Missense Mutation (SNP) | VAF 88/129 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV99639766; called by muse, mutect2, varscan2
- CEP70 | c.337A>G p.N113D | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV99389516; called by muse, mutect2, varscan2
- CFH | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 210/291 reads (72%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); catalogued as CM086802, COSV100661621, COSV104415169; called by muse, mutect2, varscan2
- CHGA | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99381276; called by muse, mutect2, varscan2
- CLCA1 | c.2574C>A p.N858K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99322770; called by muse, mutect2, varscan2
- CLCA1 | c.2575A>G p.I859V | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV99322771; called by muse, mutect2, varscan2
- COL12A1 | c.3161G>T p.R1054L | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs577784031, COSV100486418; called by muse, mutect2, varscan2
- COMP | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99721566; called by muse, mutect2, varscan2
- DDX4 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs770112379, COSV100737765; called by muse, mutect2, varscan2
- DES | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV64660820; called by muse, mutect2, varscan2
- DGAT2L6 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV100284144; called by muse, mutect2, varscan2
- DNAH3 | c.266C>G p.T89R | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.069); catalogued as COSV99770351; called by muse, mutect2, varscan2
- DNAJB8 | c.566T>G p.I189S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV100048482; called by muse, mutect2, varscan2
- DNMT3A | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99264300; called by muse, mutect2, varscan2
- ELOA | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV101403825; called by muse, mutect2, varscan2
- EPHA4 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs765523420, COSV56025824; called by muse, mutect2, varscan2
- ESS2 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99351200; called by muse, mutect2, varscan2
- FBXO28 | c.902A>G p.Q301R | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.932); catalogued as COSV100837483; called by muse, mutect2, varscan2
- GABRB1 | c.269A>C p.Q90P | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99783329; called by muse, mutect2, varscan2
- GALNT13 | c.896G>T p.R299I | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV101223796, COSV67220220; called by muse, mutect2, varscan2
- GGT7 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV60540972, COSV60541014; called by muse, mutect2, varscan2
- GGT7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs981539249, COSV99490198; called by muse, mutect2, varscan2
- GPR61 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs752917891, COSV68177668; called by muse, mutect2, varscan2
- HECTD4 | c.4546G>A p.A1516T | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as rs777014921, COSV66397839; called by muse, mutect2, varscan2
- HSDL2 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV99357120; called by muse, mutect2, varscan2
- HTR1A | c.789G>C p.W263C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV100109264; called by muse, mutect2, varscan2
- HYAL3 | c.1157G>T p.S386I | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100269807; called by muse, mutect2, varscan2
- IFNA5 | c.174C>G p.D58E | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99423767; called by muse, mutect2, varscan2
- ITIH5 | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.831); catalogued as rs1221205644, COSV99905635; called by muse, mutect2, varscan2
- KCNH4 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99237567, COSV99237856; called by muse, mutect2, varscan2
- KCNJ3 | c.1217T>A p.I406N | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as COSV99716405; called by muse, mutect2, varscan2
- KIAA0100 | c.1619A>C p.Q540P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.209); catalogued as COSV101197404; called by muse, mutect2, varscan2
- KIAA2026 | c.3867_3868del p.G1290Sfs*54 | Frame Shift Del (DEL) | VAF 49/174 reads (28%) | catalogued as rs778199550; called by mutect2, pindel, varscan2
- KIF26A | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100181529; called by muse, mutect2, varscan2
- KLHL23 | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1256653928, COSV99776105; called by muse, mutect2, varscan2
- KLHL41 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as rs151212497; called by muse, mutect2, varscan2
- LAD1 | c.935C>A p.A312D | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100943934; called by muse, mutect2, varscan2
- LPXN | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV101223130; called by muse, mutect2
- LUM | c.640A>T p.N214Y | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99899186; called by muse, mutect2, varscan2
- LY6G5B | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV101020853; called by muse, mutect2, varscan2
- MAGEA11 | c.888C>G p.N296K | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100290683; called by muse, mutect2, varscan2
- MAGI3 | c.1153A>C p.I385L | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV100290329; called by muse, mutect2, varscan2
- MAN2A1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99811833; called by muse, mutect2, varscan2
- MFSD2A | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779813409, COSV100861734; called by muse, mutect2, varscan2
- MGA | c.8033G>T p.S2678I (on ENST00000219905 / NM_001164273.1; = p.S2469I on NM_001080541.2) | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99581418; called by muse, mutect2, varscan2
- MIGA1 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100889809; called by muse, mutect2, varscan2
- MUC5B | c.11273C>T p.T3758M | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs765539013, COSV101500727; called by muse, mutect2, varscan2
- MYCBP2 | c.7716A>T p.R2572S (on ENST00000357337; = p.R2610S on NM_015057.5) | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100631743; called by muse, mutect2, varscan2
- NSD1 | c.7438G>A p.D2480N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as COSV61771700; called by muse, mutect2, varscan2
- NWD1 | c.4619A>T p.Q1540L | Missense Mutation (SNP) | VAF 109/180 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100343614; called by muse, mutect2, varscan2
- OR51V1 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as rs558002486, COSV100343506; called by muse, mutect2, varscan2
- OR6B1 | c.580A>G p.I194V | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1198378129, COSV101281670; called by muse, mutect2, varscan2
- P2RY10 | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as COSV50683000; called by muse, mutect2, varscan2
- PCDH1 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99746910; called by muse, mutect2, varscan2
- PCDHB15 | c.1218A>T p.E406D | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.02); catalogued as COSV99179167; called by muse, mutect2, varscan2
- PDZD11 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99333840; called by muse, mutect2, varscan2
- PIGQ | c.2186A>C p.K729T | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV99216506; called by muse, mutect2, varscan2
- PKD2L2 | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296666; called by muse, mutect2, varscan2
- POPDC3 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99633253; called by muse, mutect2, varscan2
- PPIC | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV100120631; called by muse, mutect2, varscan2
- PPP1R12C | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99670362; called by muse, mutect2, varscan2
- PRAG1 | c.2930G>T p.G977V | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.528); catalogued as COSV100422770; called by muse, mutect2, varscan2
- PRDM10 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100702183; called by muse, mutect2, varscan2
- PSTPIP1 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99143953; called by muse, mutect2, varscan2
- PTPA | c.358G>C p.D120H (on ENST00000337738 / NM_178001.2; = p.D85H on NM_021131.5) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100534190; called by muse, mutect2, varscan2
- PTPN13 | c.23C>A p.A8D | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100365394; called by muse, mutect2, varscan2
- PTPRC | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100723129; called by muse, mutect2, varscan2
- RAB11FIP1 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99770443; called by muse, mutect2, varscan2
- RAB3D | c.277C>G p.R93G | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55792780, COSV99708946; called by muse, mutect2, varscan2
- REST | c.1706A>G p.K569R | Missense Mutation (SNP) | VAF 159/231 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as rs541994823, COSV100471313; called by muse, mutect2, varscan2
- RSC1A1 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186136042, COSV100197879; called by muse, mutect2, varscan2
- SLBP | c.411G>C p.R137S | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100571411; called by muse, mutect2, varscan2
- SLC1A3 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99468184; called by muse, mutect2, varscan2
- SPEG | c.6007G>T p.A2003S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100405546; called by muse, mutect2, varscan2
- SPTA1 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV100935516; called by muse, mutect2, varscan2
- TAF5 | c.1134A>T p.K378N | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100674758; called by muse, mutect2, varscan2
- TBC1D19 | c.574A>T p.K192* | Nonsense Mutation (SNP) | VAF 29/41 reads (71%) | catalogued as COSV99336774; called by muse, mutect2, varscan2
- TBX3 | c.2165A>T p.Q722L (on ENST00000257566 / NM_016569.4; = p.Q702L on NM_005996.4) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99984081; called by muse, mutect2, varscan2
- TEKT2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.129); catalogued as COSV99255619; called by muse, mutect2, varscan2
- TP53BP2 | c.1979A>G p.Q660R (on ENST00000343537 / NM_001031685.3; = p.Q531R on NM_005426.2) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs1226461600, COSV100636796; called by muse, mutect2, varscan2
- TP53INP1 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100711135; called by muse, mutect2
- TRAF7 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100399821; called by muse, mutect2, varscan2
- TREX2 | c.239G>C p.R80P (on ENST00000334497; = p.R37P on NM_080701.3) | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782408064, COSV100444294, COSV57847905; called by muse, mutect2, varscan2
- TRIM55 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV52549509; called by muse, mutect2, varscan2
- TTN | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 16/139 reads (12%) | PolyPhen probably damaging (0.965); catalogued as rs750730828, COSV100628200, COSV60267535; called by muse, mutect2, varscan2
- USP2 | c.190C>A p.R64S | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV99489952; called by muse, mutect2, varscan2
- USP40 | c.464A>G p.H155R | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.765); catalogued as rs748776669, COSV99297088; called by muse, mutect2, varscan2
- WAPL | c.1375A>C p.S459R | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100077232; called by muse, mutect2, varscan2
- WNK3 | c.3343G>T p.E1115* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100672051; called by muse, mutect2, varscan2
- XRCC5 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101079863; called by muse, mutect2, varscan2
- ZC3H4 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99452757; called by muse, mutect2, varscan2
- ZFP82 | c.1154A>G p.H385R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV101089305; called by muse, mutect2, varscan2
- ZNF215 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as COSV99549905; called by muse, mutect2, varscan2
- ZNF804A | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV100165828; called by muse, mutect2, varscan2
- ZNF816 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.528); catalogued as COSV99554695; called by muse, mutect2, varscan2
- ZP1 | c.1455C>A p.Y485* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV99612801; called by muse, mutect2, varscan2
- CLINT1 | c.144C>A p.A48= | Splice Region (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- GJD2 | c.506del p.L169* | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- IKZF3 | c.580_589del p.R194Lfs*63 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- SCN1A | c.5868dup p.E1957Rfs*6 (on ENST00000303395 / NM_001202435.3; = p.E1946Rfs*6 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- SETD2 | c.2778del p.E927Kfs*3 | Frame Shift Del (DEL) | VAF 41/106 reads (39%) | called by mutect2, pindel, varscan2
- AATK | c.1290G>A p.A430= (on ENST00000326724 / NM_001080395.3; = p.A327= on NM_004920.2) | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100453111; called by muse, mutect2, varscan2
- ACP3 | c.888A>C p.L296= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100313568; called by muse, mutect2, varscan2
- ALPK3 | c.1692G>A p.S564= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs549394061, COSV99361919; called by muse, mutect2, varscan2
- CEP19 | c.12T>A p.T4= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99582660; called by muse, mutect2, varscan2
- DACH1 | c.1737G>A p.P579= (on ENST00000619232 / NM_001366712.1; = p.P325= on NM_004392.6) | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs370706409, COSV57512761; called by muse, mutect2, varscan2
- DPH1 | c.1305G>A p.P435= | Silent (SNP) | VAF 36/45 reads (80%) | catalogued as rs1399885692, COSV99559646; called by muse, mutect2, varscan2
- EBNA1BP2 | c.249T>G p.S83= | Silent (SNP) | VAF 66/112 reads (59%) | catalogued as COSV99356096; called by muse, mutect2, varscan2
- FGD1 | c.2265C>T p.A755= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100911249; called by muse, mutect2, varscan2
- FHOD1 | c.2628C>T p.D876= | Silent (SNP) | VAF 45/58 reads (78%) | catalogued as COSV99264482; called by muse, mutect2, varscan2
- FLRT2 | c.141C>A p.V47= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV100420968; called by muse, mutect2, varscan2
- GTPBP3 | c.1455C>T p.F485= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as COSV100259137; called by muse, mutect2
- HAS2 | c.936T>C p.G312= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100392154; called by muse, mutect2, varscan2
- IRAK3 | c.1227C>G p.P409= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV54160554, COSV99706446; called by muse, mutect2, varscan2
- ITGB5 | c.936C>T p.N312= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs185706140, COSV99951057; called by muse, mutect2, varscan2
- KCNJ15 | c.519G>A p.K173= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs765908603, COSV100154381; called by muse, mutect2, varscan2
- MYH14 | c.1734C>T p.G578= | Silent (SNP) | VAF 37/178 reads (21%) | catalogued as rs1368085212, COSV99223976; called by muse, mutect2, varscan2
- NCOR2 | c.4308G>A p.T1436= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs779461576, COSV100657839; called by muse, mutect2, varscan2
- OS9 | c.18G>T p.L6= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV99233094; called by muse, mutect2, varscan2
- P2RY10 | c.978C>A p.S326= | Silent (SNP) | VAF 81/184 reads (44%) | catalogued as rs763969815, COSV50680735, COSV99409372; called by muse, mutect2, varscan2
- PCDHGB5 | c.1032A>G p.T344= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.792C>T p.A264= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs778071325, COSV100773138, COSV63047950; called by muse, mutect2, varscan2
- PRDM4 | c.108G>A p.L36= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs370718612; called by muse, mutect2, varscan2
- PTPN22 | c.1188A>G p.K396= (on ENST00000359785 / NM_001193431.2; = p.K341= on NM_012411.5) | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100703916; called by muse, mutect2, varscan2
- RNF128 | c.93G>A p.P31= | Silent (SNP) | VAF 55/207 reads (27%) | catalogued as COSV99718493; called by muse, mutect2, varscan2
- SELE | c.525G>A p.E175= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV100325115; called by muse, mutect2, varscan2
- SIRT3 | c.999C>T p.A333= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs376721867; called by muse, mutect2, varscan2
- SPON1 | c.516A>G p.Q172= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs976146655, COSV100116596; called by muse, mutect2, varscan2
- SYP | c.912T>A p.G304= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as COSV99603077; called by muse, varscan2
- TAS1R1 | c.402C>T p.L134= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100063469; called by muse, mutect2, varscan2
- TBC1D19 | c.573A>G p.V191= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV99336771; called by muse, mutect2, varscan2
- TCOF1 | c.2203T>C p.L735= (on ENST00000377797 / NM_001135243.1; = p.L658= on NM_000356.4) | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV100078302; called by muse, mutect2, varscan2
- TRIM67 | c.2154C>T p.T718= | Silent (SNP) | VAF 58/325 reads (18%) | catalogued as rs200465476; called by muse, mutect2, varscan2
- ZHX1 | c.1089A>T p.V363= | Silent (SNP) | VAF 23/216 reads (11%) | catalogued as COSV99933866; called by muse, mutect2, varscan2
- ZMYND8 | c.1182G>A p.Q394= (on ENST00000311275 / NM_001363741.2; = p.Q414= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as COSV99521244; called by muse, mutect2, varscan2
- ZNF197 | c.723G>A p.L241= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV100482242, COSV60360495; called by muse, mutect2, varscan2
- ATAD3B | c.*593C>T | 3'UTR (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100426604; called by muse, varscan2
- DNAH8 | chr6:38722889 G>A | 5'Flank (SNP) | VAF 24/42 reads (57%) | catalogued as rs760061997, COSV59422094; called by muse, mutect2, varscan2
- HERC2P3 | n.824A>G | RNA (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MIR9-1HG | n.477A>C | RNA (SNP) | VAF 37/216 reads (17%) | catalogued as COSV100024323; called by muse, mutect2, varscan2
- PML | c.1710+1414G>T | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99167859; called by muse, mutect2, varscan2
- SSPOP | n.7052G>A | RNA (SNP) | VAF 27/58 reads (47%) | catalogued as COSV100022952; called by muse, mutect2, varscan2
